Somatic mutation profile of tumor specimen HCM-CSHL-0058-C34-01B (aliquot HCM-CSHL-0058-C34-01B-01D-A78L-36) from HCMI case HCM-CSHL-0058-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 82.8 years (30,226 days).
Specimen HCM-CSHL-0058-C34-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15688004-2394-4da5-a5b8-fe9036bae42d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0058-C34-10A (Blood Derived Normal), aliquot HCM-CSHL-0058-C34-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da808501-0318-4ad9-b86a-40f76288c0ee

The open-access MAF lists 128 somatic variants for this specimen: 88 protein-altering or splice-affecting, 22 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 22, Intron 6, Nonsense Mutation 6, 3'UTR 4, Splice Site 4, RNA 3, 5'UTR 2, Frame Shift Del 2, 5'Flank 2, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 28/137 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AXDND1 | c.1208C>A p.A403D | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100858349; called by muse, varscan2
- CAMSAP1 | c.4217C>G p.S1406C | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV56724143; called by muse, mutect2
- CDC73 | c.1351G>T p.A451S | Missense Mutation (SNP) | VAF 40/324 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.301); catalogued as COSV100813741; called by muse, mutect2, varscan2
- CHRNB2 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as rs1215936429, COSV63807684; called by muse, mutect2
- EPB41L4A | c.1622+1G>A p.X541_splice | Splice Site (SNP) | VAF 16/130 reads (12%) | catalogued as rs1391319865; called by muse, mutect2
- FSD2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as rs781225191, COSV58008822; called by muse, mutect2, varscan2
- HRNR | c.5945C>A p.S1982Y | Missense Mutation (SNP) | VAF 26/786 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs1300554308; called by muse, mutect2
- HS3ST3B1 | c.107T>C p.L36P | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs1162912862; called by muse, mutect2
- IQGAP1 | c.3555G>A p.K1185= | Splice Region (SNP) | VAF 13/160 reads (8%) | catalogued as rs747816026; called by muse, mutect2
- ITPR2 | c.1249-2A>G p.X417_splice | Splice Site (SNP) | VAF 5/17 reads (29%) | catalogued as rs1565689068; called by muse, mutect2, varscan2
- JAKMIP3 | c.1645C>T p.R549W | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs761765135, COSV100058525; called by muse, mutect2, varscan2
- MBLAC2 | c.52T>C p.W18R | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV57302536; called by muse, mutect2, varscan2
- NT5DC4 | c.395C>A p.T132N | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1479236828; called by muse, mutect2, varscan2
- OR5T3 | c.745G>T p.A249S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as rs780402245, COSV57381889; called by muse, mutect2, varscan2
- PREP | c.1729C>G p.R577G (on ENST00000369110; = p.R643G on NM_002726.5) | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64873128; called by muse, mutect2, varscan2
- RBM10 | c.1873G>T p.G625* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV61310019; called by muse, mutect2, varscan2
- RIMS1 | c.2894C>A p.P965Q | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV53471056; called by muse, mutect2
- SALL4 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV53852323; called by mutect2, varscan2
- SLC2A4RG | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.091); catalogued as COSV99829384; called by muse, mutect2
- SORCS1 | c.1940+1G>A p.X647_splice | Splice Site (SNP) | VAF 15/58 reads (26%) | catalogued as rs1447669165, COSV53872995; called by muse, varscan2
- SSU72P8 | c.305C>A p.T102N | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV66361273; called by mutect2, varscan2
- TAAR9 | c.103C>T p.L35F | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs761234107; called by muse, mutect2, varscan2
- TAF1A | c.776T>C p.V259A | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV61917808; called by muse, varscan2
- TENM3 | c.2407C>A p.Q803K | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs753495814; called by muse, mutect2, varscan2
- TPO | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.194); catalogued as COSV100222346, COSV61110138; called by muse, mutect2, varscan2
- TPO | c.908C>A p.A303E | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.559); catalogued as rs1327228715, COSV61111044; called by muse, mutect2, varscan2
- TYW1B | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as rs782331205; called by muse, varscan2
- VWC2 | c.809G>A p.C270Y | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV61487351; called by muse, varscan2
- ZMYND10 | c.327C>A p.H109Q | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51602012; called by muse, mutect2, varscan2
- ZNF232 | c.980G>C p.G327A | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1292671430; called by muse, mutect2, varscan2
- ZNF716 | c.546G>T p.K182N | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as COSV101348735; called by muse, mutect2, varscan2
- ABCA12 | c.1660C>A p.Q554K (on ENST00000272895 / NM_173076.3; = p.Q236K on NM_015657.3) | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKR1C8P | c.176A>T p.Q59L | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AKT2 | c.1264-2A>T p.X422_splice | Splice Site (SNP) | VAF 25/197 reads (13%) | called by muse, mutect2, varscan2
- CCDC39 | c.1519A>T p.K507* | Nonsense Mutation (SNP) | VAF 17/146 reads (12%) | called by muse, mutect2, varscan2
- CNTN2 | c.55C>A p.L19I | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DSPP | c.906A>T p.K302N | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELAC1 | c.118G>C p.G40R | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ELK4 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 11/259 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EMSY | c.3161A>T p.Q1054L | Missense Mutation (SNP) | VAF 23/260 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- EPHA5 | c.1865G>C p.G622A | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- ERC1 | c.2032_2046del p.L678_A682del (on ENST00000360905 / NM_178040.4; = p.L650_A654del on NM_178039.4) | In Frame Del (DEL) | VAF 3/29 reads (10%) | called by mutect2, pindel
- EVC | c.2558A>G p.Q853R | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2
- FBN2 | c.8371C>A p.Q2791K | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- FNDC3B | c.2599C>G p.L867V | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- FSIP2 | c.8440C>G p.Q2814E | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, varscan2
- GJC2 | c.760G>T p.V254L | Missense Mutation (SNP) | VAF 68/301 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INAVA | c.1841T>G p.V614G | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2
- IQGAP1 | c.2839G>C p.D947H | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.701); called by muse, mutect2
- KCNA5 | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- KLF7 | c.226_230del p.L77Pfs*12 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel
- LAMA2 | c.7104C>A p.F2368L | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRCOL1 | c.393C>A p.H131Q | Missense Mutation (SNP) | VAF 14/89 reads (16%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LYST | c.4913C>T p.S1638L | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2
- MARCHF11 | c.602T>A p.L201Q | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MED1 | c.3278G>A p.G1093D | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- MGA | c.5680G>T p.V1894L (on ENST00000219905 / NM_001164273.1; = p.V1685L on NM_001080541.2) | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MUC17 | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.54); called by muse, mutect2
- MUC2 | c.1235C>A p.S412Y | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MYH11 | c.3988C>A p.Q1330K | Missense Mutation (SNP) | VAF 37/249 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- NDUFB2 | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- NPHS1 | c.2975C>A p.P992Q | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- NR5A2 | c.1552T>C p.Y518H (on ENST00000367362 / NM_205860.3; = p.Y472H on NM_003822.5) | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); called by muse, varscan2
- OR2H1 | c.375C>A p.C125* | Nonsense Mutation (SNP) | VAF 17/96 reads (18%) | called by muse, mutect2, varscan2
- OR5H15 | c.358T>A p.Y120N | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PARM1 | c.847A>T p.R283W | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHGA2 | c.2105G>C p.C702S | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); called by muse, mutect2
- PCYT1A | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 19/181 reads (10%) | called by muse, mutect2, varscan2
- PER2 | c.3556G>A p.E1186K | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- PIP4K2C | c.758A>G p.Y253C | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.18); called by muse, varscan2
- POTEC | c.395G>C p.R132T | Missense Mutation (SNP) | VAF 44/339 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RASEF | c.482G>C p.R161T | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RHAG | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, varscan2
- RP1L1 | c.1649G>T p.G550V | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- SHC2 | c.1046dup p.G351Rfs*85 | Frame Shift Ins (INS) | VAF 7/59 reads (12%) | called by mutect2, pindel, varscan2
- SLC10A2 | c.676C>A p.L226M | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- SLC10A3 | c.1249G>T p.V417F | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SNTA1 | c.473C>G p.T158R | Missense Mutation (SNP) | VAF 12/215 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- SPTY2D1 | c.1066A>G p.M356V | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNE1 | c.7589G>T p.W2530L (on ENST00000367255 / NM_182961.4; = p.W2537L on NM_033071.3) | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- TMEM236 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 34/273 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPH2 | c.1217G>T p.C406F | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- TRPM1 | c.2610C>A p.S870R | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- UBE2QL1 | c.403A>T p.K135* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2, varscan2
- WDR70 | c.823G>T p.D275Y | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFP2 | c.311G>T p.C104F | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF107 | c.891del p.K298Nfs*16 | Frame Shift Del (DEL) | VAF 9/76 reads (12%) | called by mutect2, pindel, varscan2
- ADAMTS3 | c.3168C>T p.T1056= | Silent (SNP) | VAF 12/95 reads (13%) | called by muse, mutect2, varscan2
- BEND6 | c.435C>T p.A145= | Silent (SNP) | VAF 10/167 reads (6%) | catalogued as COSV66069512; called by muse, mutect2
- CADPS | c.657G>A p.V219= | Silent (SNP) | VAF 18/133 reads (14%) | called by muse, mutect2, varscan2
- DLGAP3 | c.754C>A p.R252= | Silent (SNP) | VAF 37/94 reads (39%) | called by muse, mutect2, varscan2
- FER1L6 | c.1374C>A p.T458= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as rs527654182; called by mutect2, varscan2
- FEZ1 | c.853C>A p.R285= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs1347208502, COSV54026913; called by muse, mutect2, varscan2
- FOXL1 | c.132C>A p.A44= | Silent (SNP) | VAF 14/131 reads (11%) | called by muse, mutect2, varscan2
- KRT9 | c.1839C>T p.Y613= | Silent (SNP) | VAF 18/147 reads (12%) | catalogued as rs142173628; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO1F | c.2175G>A p.L725= | Silent (SNP) | VAF 23/258 reads (9%) | called by muse, mutect2
- NT5DC4 | c.396C>A p.T132= | Silent (SNP) | VAF 22/182 reads (12%) | called by muse, mutect2, varscan2
- OR5H2 | c.219T>C p.F73= | Silent (SNP) | VAF 10/70 reads (14%) | called by muse, varscan2
- PCDHA10 | c.1899G>T p.T633= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as rs782434773, COSV56477279; called by muse, mutect2, varscan2
- PCDHA11 | c.2121C>A p.S707= | Silent (SNP) | VAF 25/106 reads (24%) | called by muse, mutect2, varscan2
- RAD50 | c.2505A>G p.K835= | Silent (SNP) | VAF 10/157 reads (6%) | catalogued as rs996373843; ClinVar: likely benign; called by muse, mutect2
- RXFP3 | c.927C>A p.A309= | Silent (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- SNX29 | c.1965G>T p.R655= | Silent (SNP) | VAF 20/161 reads (12%) | called by muse, mutect2, varscan2
- SPHKAP | c.3891G>T p.G1297= | Silent (SNP) | VAF 4/37 reads (11%) | called by muse, varscan2
- ST3GAL5 | c.1074C>A p.L358= (on ENST00000377332; = p.L398= on NM_003896.4) | Silent (SNP) | VAF 7/108 reads (6%) | called by muse, mutect2
- TG | c.1959T>A p.G653= | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, varscan2
- TM7SF2 | c.801G>A p.V267= | Silent (SNP) | VAF 12/112 reads (11%) | called by mutect2, varscan2
- TNFRSF21 | c.1779C>T p.P593= | Silent (SNP) | VAF 17/125 reads (14%) | called by muse, mutect2, varscan2
- WDR64 | c.2352C>A p.I784= | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as rs944206059; called by muse, varscan2
- ADGRV1 | c.*18G>A | 3'UTR (SNP) | VAF 47/235 reads (20%) | catalogued as rs368671859; called by muse, mutect2, varscan2
- ATG4B | c.812-67C>T | Intron (SNP) | VAF 9/84 reads (11%) | catalogued as rs755654689; called by muse, mutect2, varscan2
- CCDC162P | n.2474T>A | RNA (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2
- DNAH14 | c.1033-4614C>A | Intron (SNP) | VAF 20/132 reads (15%) | catalogued as COSV64788756; called by muse, varscan2
- EPHB1 | c.-81G>C | 5'UTR (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2
- HAS1 | chr19:51723978 C>T | 5'Flank (SNP) | VAF 19/113 reads (17%) | called by muse, mutect2, varscan2
- HERC2P2 | n.2997G>C | RNA (SNP) | VAF 18/368 reads (5%) | called by muse, mutect2
- LINC01193 | n.792G>T | RNA (SNP) | VAF 20/509 reads (4%) | called by muse, mutect2
- NLGN4Y | c.*1039G>C | 3'UTR (SNP) | VAF 25/218 reads (11%) | catalogued as rs914603689, COSV104410747; called by muse, varscan2
- OSCAR | c.*400G>T | 3'UTR (SNP) | VAF 7/134 reads (5%) | catalogued as rs765318712; called by muse, mutect2
- PA2G4 | chr12:56104544 C>A | 5'Flank (SNP) | VAF 14/250 reads (6%) | called by muse, mutect2
- PCDHB6 | chr5:141157700 A>G | 3'Flank (SNP) | VAF 23/275 reads (8%) | called by muse, mutect2, varscan2
- PKP1 | c.-38C>A | 5'UTR (SNP) | VAF 18/92 reads (20%) | called by muse, varscan2
- PMS2 | c.*152C>G | 3'UTR (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- SCIN | c.200-485G>T | Intron (SNP) | VAF 29/231 reads (13%) | catalogued as rs1475657534; called by muse, mutect2, varscan2
- SCIN | c.200-484G>T | Intron (SNP) | VAF 29/229 reads (13%) | catalogued as rs1165293304; called by muse, mutect2, varscan2
- SERPINA3 | c.-8-16G>T | Intron (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- UGT1A6 | c.862-23334C>T | Intron (SNP) | VAF 18/192 reads (9%) | catalogued as rs373107890; called by muse, mutect2
